Gene-level copy-number profile of tumor specimen TCGA-FP-A4BE-01A from TCGA case TCGA-FP-A4BE, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 55.2 years (20,148 days).
Specimen TCGA-FP-A4BE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.24e20c8a-d4c6-4c8a-91e7-b3b98cbab616.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FP-A4BE-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate.
https://portal.gdc.cancer.gov/files/edd380d3-813a-4f20-81cd-ad20884cf5ca

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 21; copy number 2: 422; copy number 4: 47,212; copy number 5: 810; copy number 6: 11,173; copy number 8: 135; copy number 10: 41; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 43 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,273,587–38,276,318, 2 genes, copy number 13: TRGJP, TRGJP1.
- chr14:22,086,407–22,482,959, 41 genes, copy number 10 (within-gene range 4–10): TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
